Gene-level copy-number profile of tumor specimen TCGA-BK-A4ZD-01A from TCGA case TCGA-BK-A4ZD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 42.5 years (15,536 days).
Specimen TCGA-BK-A4ZD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.631fb5a3-e799-40eb-8484-0b70bbd58006.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A4ZD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b81b48b-e13f-4bc4-bf80-7f72e68e56d0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 952; copy number 2: 11,283; copy number 3: 19,217; copy number 4: 13,170; copy number 5: 7,362; copy number 6: 3,781; copy number 7: 3,045; copy number 8: 98; copy number 9: 155; copy number 10: 550; copy number 13: 7; copy number 15: 182; copy number 21: 16; copy number 33: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A4ZD-01A-11D-A27O-01): tumor purity 0.87, ploidy 3.72, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,054 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:64,275,257–113,761,927, 746 genes, copy number 7–9 (broad region; genes not listed).
- chr6:60,719,222–170,738,536, 1,533 genes, copy number 7 (broad region; genes not listed).
- chr7:14,985,378–15,562,015, 3 genes, copy number 7 (within-gene range 4–7): GTF3AP5, AC006458.1, AGMO.
- chr7:30,115,845–30,367,689, 10 genes, copy number 7: AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1.
- chr7:30,371,508–30,372,741, 1 gene, copy number 7: AC006978.1.
- chr7:30,651,942–32,428,131, 19 genes, copy number 7 (within-gene range 4–7): CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR, ADCYAP1R1, AC006466.1, AC006398.1, AC006380.1, NEUROD6, AC005090.1, ITPRID1, PPP1R17, PDE1C, SNX2P2.
- chr7:36,153,254–37,449,249, 20 genes, copy number 7 (within-gene range 4–7): EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1, AC007349.4, AC007349.1, AC007349.3, NPM1P18, AC007349.2, ELMO1, MIR1200, ELMO1-AS1, RPS17P13.
- chr8:737,628–1,708,476, 1 gene, copy number 7 (within-gene range 5–7): DLGAP2.
- chr8:1,018,757–39,928,790, 830 genes, copy number 7 (broad region; genes not listed).
- chr8:39,914,229–39,920,890, 2 genes, copy number 7: AC007991.2, AC007991.4.
- chr8:69,667,046–89,757,812, 294 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:90,791,741–90,959,393, 1 gene, copy number 10 (within-gene range 6–10): NECAB1.
- chr8:90,958,471–93,974,776, 53 genes, copy number 10: C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1.
- chr8:95,204,456–95,811,254, 1 gene, copy number 10 (within-gene range 6–10): C8orf37-AS1.
- chr8:95,505,406–97,149,654, 17 genes, copy number 10 (within-gene range 6–10): AC083836.1, RNU6-690P, SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ.
- chr8:98,064,522–101,262,903, 79 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:102,826,308–111,757,710, 112 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:113,376,669–128,564,679, 199 genes, copy number 15–33 (broad region; genes not listed).
- chr11:62,011,751–62,888,875, 72 genes, copy number 10 (broad region; genes not listed).
- chr11:128,614,340–131,350,917, 51 genes, copy number 7 (within-gene range 5–7): AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2.
- chr11:131,385,249–131,581,145, 3 genes, copy number 7: RNU6ATAC12P, AP003025.1, AP003025.2.
- chr12:96,900,697–97,185,609, 7 genes, copy number 13: EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4.

Autosomal genes at a single copy (total copy number 1): 411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
